Somatic mutation profile of tumor specimen TARGET-10-PARHBT-09A (aliquot TARGET-10-PARHBT-09A-01D) from TARGET case TARGET-10-PARHBT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.0 years (6,213 days).
Specimen TARGET-10-PARHBT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5b5b157-8737-4ebf-9bab-7301e53e1ae7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARHBT-10B (Blood Derived Normal), aliquot TARGET-10-PARHBT-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2692e551-1dd0-49fa-b372-4c8fa6452057

The open-access MAF lists 25 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 7, Nonsense Mutation 4, Intron 3, 3'UTR 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.4930C>T p.R1644* | Nonsense Mutation (SNP) | VAF 56/130 reads (43%) | catalogued as rs140630, CM013931, COSV57331556; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRINP3 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66542484; called by muse, mutect2, varscan2
- CPA4 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772749799, COSV55984132, COSV55985226; called by muse, mutect2, varscan2
- FAT1 | c.7204C>T p.H2402Y | Missense Mutation (SNP) | VAF 73/140 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV71676172; called by muse, mutect2, varscan2
- GRIN2A | c.4010C>T p.S1337L | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV58043120; called by muse, mutect2, varscan2
- IRF1 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 50/115 reads (43%) | catalogued as COSV55376240; called by muse, mutect2, varscan2
- MRPL53 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs925154921, COSV50688696; called by muse, mutect2, varscan2
- NAT9 | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52855181; called by muse, mutect2, varscan2
- NOTCH1 | c.7171C>T p.Q2391* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV53033191; called by muse, mutect2, varscan2
- PIK3R1 | c.1354_1355insCCCTACCGCCCCTCC p.Y452delinsSLPPLH (on ENST00000521381 / NM_181523.3; = p.Y182delinsSLPPLH on NM_181504.4) | In Frame Ins (INS) | VAF 12/59 reads (20%) | catalogued as COSV57140765, COSV99073794; called by mutect2, pindel, varscan2
- RTCB | c.1059C>A p.H353Q | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53280660; called by muse, mutect2, varscan2
- SLC25A18 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769155045, COSV59409708; called by muse, mutect2, varscan2
- SPIRE1 | c.1203_1204insTAGGCCTAAT p.S402* | Nonsense Mutation (INS) | VAF 12/25 reads (48%) | called by mutect2, pindel*, varscan2*
- ENTPD4 | c.225C>T p.T75= | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as rs761352609, COSV62269564; called by muse, mutect2, varscan2
- EPB41L3 | c.2013G>A p.A671= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs375430348; called by muse, mutect2, varscan2
- EPHA8 | c.909C>T p.A303= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs369018351; called by muse, mutect2, varscan2
- MS4A4E | c.69C>T p.N23= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as COSV101301564; called by muse, mutect2, varscan2
- PCDHGA7 | c.2028C>A p.G676= | Silent (SNP) | VAF 63/152 reads (41%) | catalogued as COSV53983222; called by muse, mutect2, varscan2
- PTPRR | c.1446G>A p.Q482= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as rs1295507798; called by muse, mutect2, varscan2
- USH2A | c.5160A>C p.L1720= | Silent (SNP) | VAF 56/128 reads (44%) | called by muse, mutect2, varscan2
- AKAP1 | c.1714+774_1714+775insCCC | Intron (INS) | VAF 18/41 reads (44%) | called by mutect2, pindel, varscan2
- CD8B | c.*2C>G | 3'UTR (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- ERFE | c.*1586T>C | 3'UTR (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- MYO9B | c.2373+57C>A | Intron (SNP) | VAF 58/160 reads (36%) | called by muse, mutect2, varscan2
- PTPRR | c.628-126C>T | Intron (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
